Surgical pathology report (de-identified scan), TCGA case TCGA-W3-AA21, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-AA21-06A (Metastatic).

[page 1 of 2]
CLINICAL HISTORY

Preop diagnosis melanoma; nodular melanoma 1.1 mm Clark III-IV right shoulder 94.

GROSS DESCRIPTION

Labeled "right axillary contents": The specimen consists of fat which measures 18 x 11 x 4.5 cm. Stitch is present at one end marking apical level 3 at Hallstatt's ligament. The opposite in this specimen has no relying enhances skin ellipse which measures 5.2 x 1.9 cm. There is a longitudinal scar which measures 3 cm in length. Specimen is dissected for lymph nodes. Representative sections submitted as follows: A - skin, B - bisected apical nodes, C-J bisected lymph nodes, K-N remainder of lymph nodes.

Microscopic sections are prepared and interpreted.

ICD-O-3

DIAGNOSIS

LABELLED "RIGHT AXILLARY CONTENTS".
- FIFTY-SEVEN LYMPH NODES NEGATIVE FOR MALIGNANCY.
- SKIN AND SUBCUTANEOUS TISSUE SHOWING BIOPSY REACTION AND AN INCIDENTAL MICROEPIDERMAL INCLUSION CYST, NEGATIVE FOR MALIGNANCY.

Melanoma NOS 8720/3
Site: Lymph nodes, axilla
4/2/14
177.3

ADDENDUM

** ADDENDUM NO.1 **

This addended report supplants the prior report in its entirety.

GROSS DESCRIPTION:

Labeled "right axillary contents": The specimen consists of fat which measures 18.0 x 11.0 x 4.5 cm. Stitch is present at one end marking apical level III at Halsstead's ligament. The opposite end of this specimen has an overlying tan skin ellipse which measures 5.2 x 1.9 cm. There is a longitudinal scar which measures 3.0 cm in length. Deep to the skin there is firm red tan yellow tissue consistent with biopsy reaction. In this area there is a previously bisected nodule which measures 1.2 cm in greatest dimension. Representative sections submitted as follows: A - skin, B - bisected apical lymph nodes, C - J bisected lymph nodes, K - O and R additional lymph nodes, P, Q, S, and T biopsy site reaction area

[page 2 of 2]
and previously incised nodule.

MICROSCOPIC DESCRIPTION:

The specimen was re-examined and previously incised nodule identified and submitted for microscopic examination. It is metastatic melanoma involving a lymph node. The lymph node contour is lobulated and multinodular appearing suggesting a few matted lymph nodes. In addition, re-examination identified eight additional small lymph nodes which are negative for malignancy.

AMENDED DIAGNOSIS:

LABELED "RIGHT AXILLARY CONTENTS".

- METASTATIC MELANOMA, 1.2 CM INVOLVING LYMPH NODE, PROBABLY REPRESENTING A FEW MATTED LYMPH NODES.
- SKIN AND SUBCUTANEOUS TISSUE SHOWING BIOPSY REACTION AND AN INCIDENTAL MICROEPIDERMAL INCLUSION CYST.
- SIXTY-FIVE ADDITIONAL LYMPH NODES NEGATIVE FOR MALIGNANCY.

Signed Electronically signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 4cace7b6-eeee-4f52-b831-0700d6f84ecf (TCGA-W3-AA21.045B3EAC-1D48-4902-B1F3-54CF1DB34E48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).